TCGA case TCGA-SH-A9CU — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Papworth Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f544c652-8ee2-4bfe-a42c-41ab4b3697d1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 60 years; Vital status: Dead; Days to death: 732 days (2.0 years).

Diagnoses (3)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,135 days); Year of diagnosis: 2013; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 732 days (2.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 56 days; Days to treatment end: 178 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Days to treatment start: 481 days (1.3 years); Days to treatment end: 602 days (1.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Defactinib; Days to treatment end: 257 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 60.8 years (22,225 days); Days to diagnosis: 90 days; Prior treatment: Yes.
3. Diagnosis record without a diagnosis name: Tissue or organ of origin: Lymph node, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 60.8 years (22,225 days); Days to diagnosis: 90 days; Prior treatment: Yes.

Follow-up (8 entries)
- Day 90 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Day 90 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS.
- Days to follow up: 285 days; Disease response: With Tumor.
- Days to follow up: 449 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 602 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Preoperative.
- Karnofsky performance status: 50; Timepoint: Post Adjuvant Therapy.
- Follow-up contact recording only the day: day 732.

Molecular and laboratory tests
- Creatinine 89 mg/dL [Blood test normal range lower: 35; Blood test normal range upper: 125].

Exposures
- Occupation type: Building Frame and Related Trades Workers.
- Exposure type: Asbestos; Exposure duration years: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SH-A9CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 550 mg.
  Slide TCGA-SH-A9CU-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-SH-A9CU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SH-A9CU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Construction and Extraction; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Follow-up form 3, New tumor event 1: New tumor event site other: Ipsilateral Chest Cavity.
- Follow-up form 3, New tumor event 2: New tumor event site other: Ipsilateral Lymph Nodes.
- Drug treatment 1: Clinical trial drug classification: Defactinib/placebo.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 732 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 732 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 732 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SH-A9CU-01A-11D-A39Q-01): tumor purity 0.71, ploidy 3.25, whole-genome doublings 1.
